Somatic mutation profile of tumor specimen TCGA-FP-7735-01A (aliquot TCGA-FP-7735-01A-11D-2053-08) from TCGA case TCGA-FP-7735, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 77.3 years (28,232 days).
Specimen TCGA-FP-7735-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27bd2108-40cb-4092-b4c2-0aab47afd788.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FP-7735-10A (Blood Derived Normal), aliquot TCGA-FP-7735-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7eb4c2de-2319-4c1d-88bd-6c1f0c5e8e10

The open-access MAF lists 58 somatic variants for this specimen: 42 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 15, Splice Site 3, Frame Shift Del 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 19/42 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as rs778049752, COSV64673239; called by muse, mutect2, varscan2
- AFF3 | c.3089C>T p.T1030M | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as rs530073150, COSV57848496; called by muse, mutect2
- AMD1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64387352; called by muse, mutect2, varscan2
- ANK3 | c.2260G>C p.A754P | Missense Mutation (SNP) | VAF 32/361 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55056161; called by muse, mutect2
- ANPEP | c.1179G>T p.Q393H | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55591215; called by muse, mutect2, varscan2
- APLP1 | c.1930T>C p.Y644H (on ENST00000221891 / NM_001024807.3; = p.Y643H on NM_005166.4) | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55703069; called by muse, mutect2
- ASAH2 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757215251, COSV61483251; called by muse, mutect2, varscan2
- C10orf82 | c.326C>A p.A109E | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.929); catalogued as COSV65024574; called by muse, mutect2, varscan2
- CAVIN2 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.216); catalogued as COSV58424034; called by muse, mutect2, varscan2
- CLEC9A | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs149852205; called by muse, mutect2, varscan2
- DSEL | c.1449C>A p.N483K | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100025572; called by muse, mutect2
- ERBB3 | c.3544C>G p.L1182V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1287088483, COSV57252311; called by muse, mutect2, varscan2
- ERMP1 | c.1434T>G p.I478M | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs1289105399, COSV53037269; called by muse, mutect2, varscan2
- FLG | c.1350C>A p.H450Q | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.995); catalogued as COSV64241251; called by muse, mutect2
- GANAB | c.2322+1G>A p.X774_splice | Splice Site (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99641953; called by muse, varscan2
- GPALPP1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as COSV62705721; called by muse, mutect2
- H3C10 | c.119A>C p.H40P | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as COSV60797616; called by muse, mutect2, varscan2
- HMCN1 | c.16658G>A p.R5553Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs148530862; called by muse, mutect2, varscan2
- HTR3A | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs139646314; called by muse, mutect2, varscan2
- KANSL3 | c.1864C>A p.L622I (on ENST00000666923 / NM_001349262.2; = p.L596I on NM_001115016.3) | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV62617072; called by muse, mutect2, varscan2
- KIRREL2 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 70/120 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143964977, COSV52880797; called by muse, mutect2, varscan2
- KPNB1 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.051); catalogued as COSV51596744; called by muse, mutect2, varscan2
- L1CAM | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.326); catalogued as rs782155168, COSV62826813; called by muse, mutect2, varscan2
- LATS2 | c.2494A>G p.R832G | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV66875183; called by muse, mutect2, varscan2
- NDEL1 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765053880, COSV55326803; called by muse, mutect2, varscan2
- NUGGC | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs369064910, COSV100429502; called by muse, mutect2, varscan2
- OR8H3 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 7/177 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57908144, COSV57908895; called by muse, mutect2
- PARP8 | c.185-1G>A p.X62_splice | Splice Site (SNP) | VAF 7/50 reads (14%) | catalogued as COSV55866209; called by muse, mutect2, varscan2
- PHF3 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50317585; called by muse, mutect2
- PRKCSH | c.599-1G>A p.X200_splice | Splice Site (SNP) | VAF 5/75 reads (7%) | catalogued as COSV52951239; called by muse, mutect2
- PTEN | c.83T>G p.I28S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100911169, COSV64296071, COSV64296742; called by muse, mutect2
- RPL9 | c.379C>G p.R127G | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV54695607; called by muse, mutect2, varscan2
- SLC17A6 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs868184076, COSV54135939; called by muse, mutect2, varscan2
- SLC39A10 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62766572, COSV62767189; called by muse, mutect2
- SLC6A16 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV60027828; called by muse, mutect2, varscan2
- UMODL1 | c.1727C>T p.T576M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as rs749980330, COSV61159944; called by muse, mutect2, varscan2
- USP53 | c.414C>G p.S138R | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as COSV56794131; called by muse, mutect2
- WASHC2A | c.26A>G p.Q9R | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as rs782595391, COSV50953757; called by muse, mutect2
- WSCD1 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as rs367620024; called by muse, mutect2
- APC | c.4655_4656del p.E1552Gfs*6 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by pindel, varscan2
- DNAJC6 | c.2228del p.H743Pfs*12 | Frame Shift Del (DEL) | VAF 44/91 reads (48%) | called by mutect2, pindel, varscan2
- AKAP10 | c.1081C>A p.R361= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV99855388; called by muse, mutect2
- ARHGEF26 | c.2610C>T p.N870= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs756958138, COSV62845976; called by muse, mutect2, varscan2
- ARMC2 | c.1872G>A p.L624= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs1425397985, COSV64551024; called by muse, mutect2, varscan2
- C10orf120 | c.828C>T p.I276= | Silent (SNP) | VAF 60/124 reads (48%) | catalogued as rs200543036; called by muse, mutect2, varscan2
- CDAN1 | c.2433G>A p.S811= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as rs766040108, COSV62331815; called by muse, mutect2, varscan2
- CSDE1 | c.1815G>A p.L605= (on ENST00000358528 / NM_001007553.3; = p.L574= on NM_007158.6) | Silent (SNP) | VAF 13/188 reads (7%) | catalogued as rs1356286594, COSV54745558; called by muse, mutect2
- DCLRE1C | c.492G>A p.L164= (on ENST00000378278 / NM_001350965.2; = p.L49= on NM_022487.4) | Silent (SNP) | VAF 46/168 reads (27%) | catalogued as rs1234324028, COSV63183193; called by muse, mutect2, varscan2
- DENND6A | c.868C>T p.L290= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- IFIT1 | c.87C>T p.D29= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs779730712, COSV65661386; called by muse, mutect2, varscan2
- IGHV3-16 | c.111G>A p.L37= | Silent (SNP) | VAF 11/181 reads (6%) | called by muse, mutect2
- LGALS1 | c.108C>T p.G36= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as COSV53222039; called by muse, mutect2, varscan2
- MLIP | c.933C>A p.T311= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs780054321, COSV51429288; called by muse, mutect2, varscan2
- NCAPG2 | c.876C>T p.H292= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as rs925375163, COSV51987252; called by muse, mutect2
- PRKDC | c.8451G>A p.L2817= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV58050891; called by muse, mutect2, varscan2
- SAGE1 | c.258A>T p.I86= | Silent (SNP) | VAF 92/146 reads (63%) | catalogued as COSV61013101; called by muse, mutect2, varscan2
- ACSL5 | c.-144C>T | 5'UTR (SNP) | VAF 7/138 reads (5%) | catalogued as COSV100634558; called by muse, mutect2
